Somatic mutation profile of tumor specimen TCGA-AC-A6NO-01A (aliquot TCGA-AC-A6NO-01A-12D-A33E-09) from TCGA case TCGA-AC-A6NO, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 43.8 years (15,996 days).
Specimen TCGA-AC-A6NO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a36201df-688c-443d-81a7-d0041e373f44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A6NO-10A (Blood Derived Normal), aliquot TCGA-AC-A6NO-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54541ffa-9752-49b1-8d53-d39187a369ee

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 17, Silent 9, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNF1B | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as rs1800575, CM971467; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 16/76 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC018630.4 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV99958559; called by muse, mutect2, varscan2
- ADGRG4 | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs141974170, COSV99796188; called by muse, mutect2, varscan2
- CD6 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV57841005; called by muse, mutect2, varscan2
- DNM3 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.904); catalogued as COSV62457476; called by muse, mutect2, varscan2
- DOCK10 | c.3974G>A p.R1325Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.743); catalogued as rs745850719, COSV51347560; called by muse, mutect2, varscan2
- EXO1 | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV62217566; called by muse, mutect2, varscan2
- GATA3 | c.938del p.A313Efs*42 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | catalogued as COSV60520107; called by mutect2, pindel, varscan2
- GSAP | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 96/155 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1429696544, COSV99990385; called by muse, mutect2, varscan2
- MAGEH1 | c.646T>C p.Y216H | Missense Mutation (SNP) | VAF 72/135 reads (53%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.013); catalogued as COSV100746829; called by muse, mutect2, varscan2
- PRDM13 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760085132, COSV100980585, COSV65030985; called by muse, mutect2, varscan2
- RASGRF1 | c.2876G>C p.R959P | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV101174659; called by muse, mutect2, varscan2
- RBM15 | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.097); catalogued as rs1447598661, COSV63924566; called by muse, mutect2, varscan2
- RUNX1 | c.226C>T p.P76S (on ENST00000344691 / NM_001001890.3; = p.P103S on NM_001754.5) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55867224; called by muse, mutect2, varscan2
- SYT2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as rs138854819; called by muse, mutect2, varscan2
- TAF6L | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV53668411, COSV99585342; called by muse, mutect2, varscan2
- TBX18 | c.1378G>A p.V460M | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs535362046, COSV100858545; called by muse, mutect2, varscan2
- TCF7L2 | c.899C>T p.P300L (on ENST00000355995 / NM_001367943.1; = p.P277L on NM_030756.5) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as COSV99526383; called by muse, mutect2, varscan2
- MCTP2 | c.1417dup p.V473Gfs*5 | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- ADRA1D | c.1347C>T p.C449= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1368748984, COSV101063091; called by muse, mutect2
- BCKDK | c.234T>C p.A78= | Silent (SNP) | VAF 61/107 reads (57%) | catalogued as rs777686530, COSV99570772; called by muse, mutect2, varscan2
- GJA8 | c.894T>C p.N298= | Silent (SNP) | VAF 10/165 reads (6%) | catalogued as COSV99569574; called by muse, mutect2
- HSPG2 | c.3114C>T p.I1038= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV101020942; called by muse, mutect2, varscan2
- NPFFR1 | c.435C>A p.I145= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV99524938; called by muse, mutect2, varscan2
- RELCH | c.162G>T p.S54= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV56888241, COSV99902520; called by muse, mutect2, varscan2
- RELCH | c.163C>T p.L55= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV99902521; called by muse, mutect2, varscan2
- RTL8C | c.273C>A p.L91= | Silent (SNP) | VAF 142/246 reads (58%) | catalogued as COSV57060788; called by muse, mutect2, varscan2
- SNPH | c.795G>A p.S265= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs537448470, COSV60590980; called by muse, mutect2, varscan2
